FM case AD1219 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts.
https://portal.gdc.cancer.gov/cases/71c2b1d7-a55f-4fae-aa39-a7ad6aa1678c

Male, 61.5 years: Hepatocellular carcinoma, NOS (ICD-O-3 8170/3) of the liver; specimen biopsied or resected from the unknown primary site. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Tumor.
